Somatic mutation profile of tumor specimen MMRF_2412_1_BM_CD138pos (aliquot MMRF_2412_1_BM_CD138pos_T3_KHS5U_K14015) from MMRF case MMRF_2412, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.9 years (24,058 days).
Specimen MMRF_2412_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 675ce747-39ff-4476-b5a0-9615e8054b34.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2412_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2412_1_PB_Whole_C3_KHS5U_K14014; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aad9bcd2-773c-42dc-8e73-76cd2e8443ab

The open-access MAF lists 204 somatic variants for this specimen: 80 protein-altering or splice-affecting, 27 silent, 97 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, 3'UTR 51, Silent 27, Intron 26, Nonsense Mutation 10, RNA 6, 5'Flank 5, 5'UTR 5, 3'Flank 4, Frame Shift Del 3, Splice Region 3, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANP32B | c.86C>G p.S29* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as COSV59587524; called by muse, mutect2, varscan2
- ARHGAP28 | c.1212A>C p.K404N (on ENST00000383472 / NM_001366230.1; = p.K245N on NM_001010000.3) | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51631599; called by muse, mutect2, varscan2
- CACNA1A | c.5776G>A p.A1926T | Missense Mutation (SNP) | VAF 89/282 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.388); catalogued as rs766012999; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNB2 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.034); catalogued as rs897880041, COSV56639932; called by muse, mutect2, varscan2
- CLIP1 | c.2710+1G>T p.X904_splice (on ENST00000620786 / NM_001247997.1; = p.X893_splice on NM_002956.2) | Splice Site (SNP) | VAF 61/126 reads (48%) | catalogued as COSV56800847; called by muse, mutect2, varscan2
- COLGALT2 | c.620C>T p.T207I | Missense Mutation (SNP) | VAF 55/180 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs942496699; called by muse, mutect2, varscan2
- ENPEP | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs377592598, COSV54449738; called by muse, mutect2, varscan2
- EPOR | c.110G>A p.S37N | Missense Mutation (SNP) | VAF 105/174 reads (60%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1170712373; called by muse, mutect2, varscan2
- EYS | c.1479C>A p.C493* | Nonsense Mutation (SNP) | VAF 10/25 reads (40%) | catalogued as rs774464019, COSV60994183, COSV60998400; called by muse, mutect2, varscan2
- FANCG | c.1572G>C p.W524C | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs1461242610; called by muse, mutect2, varscan2
- GAL3ST1 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 53/100 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs776743811; called by muse, mutect2, varscan2
- GMIP | c.2725C>T p.R909W | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs1020163175; called by muse, mutect2, varscan2
- IGHJ5 | c.17G>A p.W6* | Nonsense Mutation (SNP) | VAF 24/25 reads (96%) | catalogued as rs782801948; called by muse, varscan2
- IGHV2-70 | c.305C>A p.T102K | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs369201986; called by muse, varscan2
- IGKJ1 | c.39A>C p.K13N | Missense Mutation (SNP) | VAF 168/174 reads (97%) | catalogued as rs376004914; called by muse, mutect2, varscan2
- IGLL5 | c.45G>C p.E15D | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.077); catalogued as rs544778929, COSV73248964, COSV73249402; called by muse, mutect2, varscan2
- KRT78 | c.86G>A p.G29D | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1419506702; called by muse, mutect2, varscan2
- LINGO1 | c.368C>T p.T123M | Missense Mutation (SNP) | VAF 101/272 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as rs764093658, COSV62436378; called by muse, mutect2, varscan2
- MGAT5B | c.1753G>A p.A585T (on ENST00000569840 / NM_001199172.2; = p.A583T on NM_144677.3) | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs765184631, COSV56927548; called by muse, mutect2, varscan2
- MGRN1 | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as rs889925387; called by muse, mutect2, varscan2
- PASD1 | c.1327A>T p.K443* | Nonsense Mutation (SNP) | VAF 21/40 reads (53%) | catalogued as COSV64855072; called by muse, mutect2, varscan2
- PDCD6IP | c.529G>A p.V177M | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.036); catalogued as rs780276157; called by muse, mutect2, varscan2
- PNPLA7 | c.3316G>A p.V1106M | Missense Mutation (SNP) | VAF 96/343 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781143660, COSV52994620; called by muse, mutect2, varscan2
- POM121L12 | c.89C>G p.A30G | Missense Mutation (SNP) | VAF 57/167 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.42); catalogued as COSV68692563, COSV68692636; called by muse, mutect2, varscan2
- PRUNE2 | c.3988G>T p.A1330S | Missense Mutation (SNP) | VAF 82/272 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs1466506994; called by muse, mutect2, varscan2
- RALGAPA1 | c.5666A>G p.D1889G | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.078); catalogued as rs375060514; called by muse, varscan2
- RNF19B | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV99331502; called by muse, mutect2, varscan2
- SLIT2 | c.4267C>T p.H1423Y | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs200768792; called by muse, mutect2, varscan2
- SLITRK3 | c.1807C>T p.R603C | Missense Mutation (SNP) | VAF 52/106 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1219260576, COSV99578283; called by muse, mutect2
- SNX18 | c.1156G>A p.D386N | Missense Mutation (SNP) | VAF 118/234 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV57990308; called by muse, mutect2, varscan2
- ST8SIA3 | c.287C>A p.A96E | Missense Mutation (SNP) | VAF 87/193 reads (45%) | PolyPhen benign (0.011); catalogued as COSV100129626; called by muse, mutect2, varscan2
- SYT7 | c.216G>T p.K72N | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.74); PolyPhen benign (0.023); catalogued as rs745378316; called by muse, varscan2
- TGFBR2 | c.164A>T p.D55V | Missense Mutation (SNP) | VAF 74/140 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs549429104; called by muse, mutect2, varscan2
- TIGD2 | c.20G>T p.R7L | Missense Mutation (SNP) | VAF 56/242 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs775095861; called by muse, mutect2, varscan2
- TLE2 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs776142851, COSV53578272; called by muse, mutect2, varscan2
- TRPM6 | c.4877G>T p.W1626L | Missense Mutation (SNP) | VAF 138/231 reads (60%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.052); catalogued as rs772654466; called by muse, mutect2, varscan2
- UBA3 | c.706A>T p.M236L | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV62740927; called by muse, mutect2, varscan2
- WT1 | c.1001C>T p.T334M | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.445); catalogued as COSV60065369; called by muse, mutect2, varscan2
- ZNF41 | c.1753G>A p.G585R | Missense Mutation (SNP) | VAF 37/58 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.391); catalogued as rs780500096; called by muse, mutect2, varscan2
- ZNF423 | c.1691C>T p.T564M (on ENST00000563137 / NM_001379286.1; = p.T556M on NM_015069.4) | Missense Mutation (SNP) | VAF 74/76 reads (97%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); catalogued as rs573032120, COSV52190399; called by muse, mutect2, varscan2
- ZNF721 | c.2639C>T p.P880L (on ENST00000338977; = p.P892L on NM_133474.4) | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.902); catalogued as COSV100167272; called by muse, mutect2, varscan2
- ADK | c.422C>T p.A141V (on ENST00000286621; = p.A124V on NM_001123.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- AFF2 | c.1060C>G p.P354A | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- ARFGEF3 | c.3625C>T p.L1209F | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- ARNT | c.1004T>C p.F335S | Missense Mutation (SNP) | VAF 8/208 reads (4%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.959); called by muse, mutect2
- ASXL3 | c.3455T>C p.M1152T | Missense Mutation (SNP) | VAF 81/190 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ATXN7L3 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- BIRC6 | c.3131C>T p.P1044L | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CALHM3 | c.242G>C p.W81S | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- CATSPERE | c.2438del p.S813* | Frame Shift Del (DEL) | VAF 118/439 reads (27%) | called by mutect2, pindel, varscan2
- CCDC39 | c.941T>G p.L314* | Nonsense Mutation (SNP) | VAF 17/29 reads (59%) | called by muse, mutect2, varscan2
- CENPJ | c.595A>T p.S199C | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- DKK1 | c.404del p.N135Mfs*80 | Frame Shift Del (DEL) | VAF 27/70 reads (39%) | called by mutect2, pindel, varscan2
- DSCAML1 | c.2420T>G p.L807R (on ENST00000321322; = p.L747R on NM_020693.4) | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- DUSP1 | c.696dup p.I233Hfs*10 | Frame Shift Ins (INS) | VAF 63/152 reads (41%) | called by mutect2, pindel, varscan2
- DUSP2 | c.153G>A p.W51* | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2, varscan2
- GARS1 | c.248A>C p.E83A | Missense Mutation (SNP) | VAF 107/337 reads (32%) | SIFT tolerated (0.9); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GPR162 | c.164T>C p.L55P | Missense Mutation (SNP) | VAF 75/150 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRIPAP1 | c.2110T>A p.S704T | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- IGLV3-1 | c.302_323del p.E101Gfs*? | Frame Shift Del (DEL) | VAF 26/75 reads (35%) | called by pindel, varscan2
- IMPG1 | c.2302C>A p.Q768K | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIF13B | c.165G>C p.V55= | Splice Region (SNP) | VAF 9/15 reads (60%) | called by muse, mutect2, varscan2
- KRT20 | c.985C>T p.Q329* | Nonsense Mutation (SNP) | VAF 37/78 reads (47%) | called by muse, mutect2, varscan2
- LAMA3 | c.9414G>C p.L3138F (on ENST00000313654 / NM_198129.4; = p.L1529F on NM_000227.6) | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRTM1 | c.1511T>G p.I504S | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MPDZ | c.566T>C p.L189P | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NBEAL1 | c.6835-1G>A p.X2279_splice | Splice Site (SNP) | VAF 29/64 reads (45%) | called by muse, mutect2, varscan2
- NCAPG2 | c.2815C>T p.Q939* | Nonsense Mutation (SNP) | VAF 35/86 reads (41%) | called by muse, mutect2, varscan2
- NUP62CL | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 22/51 reads (43%) | called by muse, mutect2, varscan2
- OR10Z1 | c.461T>A p.L154H | Missense Mutation (SNP) | VAF 63/205 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- PRMT2 | c.575A>G p.Y192C | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- RYR2 | c.4862G>T p.C1621F | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- SPINT2 | c.337+6T>C | Splice Region (SNP) | VAF 29/110 reads (26%) | called by muse, mutect2, varscan2
- SPINT4 | c.177C>A p.Y59* | Nonsense Mutation (SNP) | VAF 70/170 reads (41%) | called by muse, mutect2
- TATDN1 | c.665-5A>G | Splice Region (SNP) | VAF 26/50 reads (52%) | called by muse, mutect2, varscan2
- TBC1D2B | c.1968A>C p.K656N | Missense Mutation (SNP) | VAF 147/233 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRBJ2-6 | c.1_2insGGT p.*1_S2insG | In Frame Ins (INS) | VAF 77/121 reads (64%) | called by mutect2, pindel*, varscan2*
- XPO7 | c.2706G>C p.M902I | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZFC3H1 | c.1935G>C p.E645D | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZNF367 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 4/69 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2
- ANKRD24 | c.852A>G p.S284= | Silent (SNP) | VAF 63/322 reads (20%) | called by muse, mutect2, varscan2
- APOB | c.2850G>A p.T950= | Silent (SNP) | VAF 89/177 reads (50%) | catalogued as rs760186219; called by muse, mutect2, varscan2
- ARHGAP32 | c.4074G>A p.A1358= (on ENST00000310343 / NM_001378025.1; = p.A1009= on NM_014715.4) | Silent (SNP) | VAF 94/223 reads (42%) | catalogued as rs773365931, COSV59854248; called by muse, mutect2, varscan2
- CEP295 | c.2355A>T p.S785= | Silent (SNP) | VAF 75/148 reads (51%) | called by muse, mutect2, varscan2
- EGR1 | c.198C>T p.S66= | Silent (SNP) | VAF 78/188 reads (41%) | catalogued as rs1449990055, COSV53517809; called by muse, varscan2
- ELANE | c.270G>A p.S90= | Silent (SNP) | VAF 89/266 reads (33%) | catalogued as rs1163809368; called by muse, mutect2, varscan2
- FNDC10 | c.654G>A p.A218= | Silent (SNP) | VAF 19/28 reads (68%) | called by muse, mutect2, varscan2
- GNLY | c.312C>T p.R104= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as rs1433493473, COSV99808820; called by muse, mutect2
- H1-3 | c.474G>A p.K158= | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as rs756684143; called by muse, mutect2, varscan2
- IGHV2-70 | c.225T>C p.D75= | Silent (SNP) | VAF 41/96 reads (43%) | catalogued as rs373801344; called by muse, varscan2
- IGHV2-70 | c.102A>C p.T34= | Silent (SNP) | VAF 26/101 reads (26%) | catalogued as rs559222113; called by muse, varscan2
- IGLV3-1 | c.264A>C p.T88= | Silent (SNP) | VAF 47/96 reads (49%) | catalogued as rs370211582; called by muse, varscan2
- IGLV3-10 | c.90A>G p.S30= | Silent (SNP) | VAF 54/102 reads (53%) | catalogued as rs563291552; called by muse, mutect2, varscan2
- JPH1 | c.969C>T p.D323= | Silent (SNP) | VAF 105/222 reads (47%) | called by muse, mutect2, varscan2
- KIF21A | c.2316C>G p.R772= (on ENST00000361418 / NM_001378440.1; = p.R759= on NM_017641.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/45 reads (53%) | called by muse, mutect2, varscan2
- MUC4 | c.2466C>T p.S822= | Silent (SNP) | VAF 47/116 reads (41%) | called by muse, mutect2, varscan2
- OR10A2 | c.633C>A p.A211= | Silent (SNP) | VAF 93/185 reads (50%) | catalogued as COSV100224894, COSV56299607; called by muse, mutect2, varscan2
- OR1J4 | c.591G>T p.L197= | Silent (SNP) | VAF 96/286 reads (34%) | catalogued as rs1204241822, COSV100534271; called by muse, mutect2, varscan2
- OR51G2 | c.702C>T p.A234= | Silent (SNP) | VAF 47/111 reads (42%) | called by muse, mutect2, varscan2
- PCDHA12 | c.513G>A p.A171= | Silent (SNP) | VAF 75/163 reads (46%) | catalogued as rs1351463699, COSV56540610; called by muse, mutect2, varscan2
- PIWIL1 | c.945G>A p.K315= | Silent (SNP) | VAF 12/163 reads (7%) | catalogued as COSV99806444; called by muse, mutect2
- RUFY4 | c.1602G>A p.R534= | Silent (SNP) | VAF 68/147 reads (46%) | catalogued as rs756814111; called by muse, mutect2, varscan2
- SIAE | c.24C>G p.L8= | Silent (SNP) | VAF 91/200 reads (46%) | called by muse, mutect2, varscan2
- SYNPR | c.12G>A p.V4= | Silent (SNP) | VAF 162/331 reads (49%) | called by muse, mutect2, varscan2
- UBA3 | c.705C>A p.P235= | Silent (SNP) | VAF 41/98 reads (42%) | called by muse, mutect2, varscan2
- XIRP2 | c.8832G>A p.P2944= (on ENST00000628543; = p.P3119= on NM_152381.6) | Silent (SNP) | VAF 261/494 reads (53%) | catalogued as rs558320173, COSV54693442; called by muse, mutect2, varscan2
- ZNF735 | c.975C>T p.Y325= | Silent (SNP) | VAF 42/159 reads (26%) | called by muse, mutect2, varscan2
- ABCC3 | c.45+239_45+253del | Intron (DEL) | VAF 13/34 reads (38%) | called by mutect2, pindel, varscan2
- AC006372.4 | n.210G>A | RNA (SNP) | VAF 54/188 reads (29%) | called by muse, mutect2, varscan2
- AC093802.1 | n.1914+9199T>C | Intron (SNP) | VAF 20/43 reads (47%) | catalogued as rs750519223; called by muse, mutect2, varscan2
- AC099782.1 | n.74+1956G>A | Intron (SNP) | VAF 107/374 reads (29%) | called by muse, mutect2, varscan2
- ADGRA1 | c.4-3856C>T | Intron (SNP) | VAF 12/66 reads (18%) | called by muse, varscan2
- AMOTL1 | c.*1658G>A | 3'UTR (SNP) | VAF 39/80 reads (49%) | called by muse, mutect2, varscan2
- AMOTL1 | c.*3216G>A | 3'UTR (SNP) | VAF 21/105 reads (20%) | called by muse, mutect2, varscan2
- ARMC1 | c.*988T>G | 3'UTR (SNP) | VAF 60/123 reads (49%) | called by muse, mutect2, varscan2
- ARPP21 | c.261+1894G>T | Intron (SNP) | VAF 23/47 reads (49%) | called by muse, mutect2, varscan2
- ASPH | c.*1229T>A | 3'UTR (SNP) | VAF 37/69 reads (54%) | called by muse, mutect2, varscan2
- BCL11B | c.*2153C>T | 3'UTR (SNP) | VAF 26/55 reads (47%) | catalogued as rs367548332; called by muse, mutect2, varscan2
- BCL7A | chr12:122021402 C>G | 5'Flank (SNP) | VAF 39/78 reads (50%) | catalogued as rs925835724, COSV55846299, COSV55846759, COSV55847493; called by muse, varscan2
- BUD31 | c.95-977C>A | Intron (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2, varscan2
- C11orf87 | c.*1693C>T | 3'UTR (SNP) | VAF 11/24 reads (46%) | called by muse, mutect2, varscan2
- C8orf34-AS1 | n.978G>A | RNA (SNP) | VAF 17/26 reads (65%) | called by muse, mutect2, varscan2
- C9orf152 | c.*232T>C | 3'UTR (SNP) | VAF 24/65 reads (37%) | called by muse, mutect2, varscan2
- CAMKV | c.*559C>T | 3'UTR (SNP) | VAF 75/134 reads (56%) | called by muse, mutect2, varscan2
- CATSPERG | c.-14-65G>A | Intron (SNP) | VAF 69/109 reads (63%) | catalogued as rs1385378725; called by muse, mutect2, varscan2
- CCDC115 | chr2:130342421 G>A | 5'Flank (SNP) | VAF 31/63 reads (49%) | catalogued as rs931853773; called by muse, mutect2, varscan2
- CD44 | c.*149T>C | 3'UTR (SNP) | VAF 18/47 reads (38%) | called by muse, mutect2, varscan2
- CDH19 | c.-3G>A | 5'UTR (SNP) | VAF 63/127 reads (50%) | catalogued as rs1394766517, COSV50956307; called by muse, mutect2, varscan2
- COMMD10 | c.*568T>C | 3'UTR (SNP) | VAF 49/228 reads (21%) | called by muse, mutect2, varscan2
- CPAMD8 | c.5567+247C>T | Intron (SNP) | VAF 4/14 reads (29%) | catalogued as rs750687060, COSV99935233; called by muse, varscan2
- CUL2 | c.*129A>G | 3'UTR (SNP) | VAF 19/42 reads (45%) | called by muse, mutect2, varscan2
- DGKB | c.*964T>C | 3'UTR (SNP) | VAF 65/185 reads (35%) | called by muse, mutect2, varscan2
- DLG2 | c.205-66020G>A | Intron (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
- DMRTB1 | c.*44G>T | 3'UTR (SNP) | VAF 45/87 reads (52%) | called by muse, mutect2, varscan2
- DPP10 | c.441+121G>A | Intron (SNP) | VAF 6/16 reads (38%) | catalogued as COSV59692042; called by muse, mutect2
- DRICH1 | c.-216G>A | 5'UTR (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2, varscan2
- DTX1 | c.-494C>G | 5'UTR (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
- ELAPOR2 | c.2169+83A>T | Intron (SNP) | VAF 17/39 reads (44%) | called by muse, mutect2, varscan2
- EMX1 | c.*92G>A | 3'UTR (SNP) | VAF 26/52 reads (50%) | called by muse, mutect2, varscan2
- FAM120A | c.*1435G>A | 3'UTR (SNP) | VAF 15/57 reads (26%) | called by muse, mutect2, varscan2
- FGD2 | c.1458+94G>A | Intron (SNP) | VAF 149/278 reads (54%) | catalogued as rs528219705, COSV51465431; called by muse, mutect2, varscan2
- FLT3LG | c.-12C>A | 5'UTR (SNP) | VAF 34/133 reads (26%) | called by muse, mutect2, varscan2
- FMN1 | c.2044-2821A>G | Intron (SNP) | VAF 33/93 reads (35%) | catalogued as rs766107144; called by muse, mutect2, varscan2
- FMNL3 | c.*853T>C | 3'UTR (SNP) | VAF 51/90 reads (57%) | called by muse, mutect2, varscan2
- FRMPD4 | c.*2144A>G | 3'UTR (SNP) | VAF 41/78 reads (53%) | called by muse, mutect2, varscan2
- GABRA3 | c.*873A>C | 3'UTR (SNP) | VAF 18/46 reads (39%) | called by muse, mutect2, varscan2
- GRIA3 | c.268+16791G>C | Intron (SNP) | VAF 40/82 reads (49%) | called by muse, mutect2, varscan2
- H2BC21 | c.*1261A>G | 3'UTR (SNP) | VAF 10/34 reads (29%) | catalogued as rs1203723844; called by muse, mutect2, varscan2
- HK2 | c.*1372C>T | 3'UTR (SNP) | VAF 23/40 reads (58%) | called by muse, mutect2, varscan2
- HS2ST1 | c.*605A>C | 3'UTR (SNP) | VAF 29/67 reads (43%) | called by muse, mutect2, varscan2
- JAGN1 | c.*617C>G | 3'UTR (SNP) | VAF 41/86 reads (48%) | called by muse, mutect2, varscan2
- KCNK10 | c.*458C>G | 3'UTR (SNP) | VAF 30/70 reads (43%) | called by muse, mutect2, varscan2
- LHFPL1 | c.*649dup | 3'UTR (INS) | VAF 36/84 reads (43%) | called by mutect2, varscan2
- LINC01558 | n.826G>T | RNA (SNP) | VAF 16/39 reads (41%) | catalogued as rs770743545; called by muse, mutect2, varscan2
- LL22NC03-63E9.3 | n.1697G>A | RNA (SNP) | VAF 52/116 reads (45%) | catalogued as rs1179318581; called by muse, mutect2, varscan2
- LMBRD2 | c.*1515A>G | 3'UTR (SNP) | VAF 34/69 reads (49%) | called by muse, mutect2, varscan2
- LPAR4 | c.*405T>A | 3'UTR (SNP) | VAF 34/60 reads (57%) | called by muse, mutect2, varscan2
- LRCH2 | c.*375T>C | 3'UTR (SNP) | VAF 17/34 reads (50%) | called by muse, mutect2, varscan2
- MAPK14 | c.*209C>T | 3'UTR (SNP) | VAF 31/57 reads (54%) | called by muse, mutect2, varscan2
- MIR519D | n.85G>C | RNA (SNP) | VAF 52/187 reads (28%) | called by muse, mutect2, varscan2
- MMP14 | c.108+445G>A | Intron (SNP) | VAF 69/140 reads (49%) | called by muse, mutect2, varscan2
- MTF2 | c.*106dup | 3'UTR (INS) | VAF 7/39 reads (18%) | catalogued as rs773984764, COSV64772634; called by pindel, varscan2*
- MVB12B | c.*532G>A | 3'UTR (SNP) | VAF 65/212 reads (31%) | catalogued as rs1358651319; called by muse, mutect2, varscan2
- MYOCD | chr17:12767572 C>T | 3'Flank (SNP) | VAF 14/33 reads (42%) | called by muse, mutect2, varscan2
- NKX2-5 | c.335-167G>A | Intron (SNP) | VAF 108/251 reads (43%) | called by muse, mutect2, varscan2
- OBSCN | c.9004+283G>A | Intron (SNP) | VAF 54/165 reads (33%) | called by muse, mutect2, varscan2
- OGT | c.*1529A>C | 3'UTR (SNP) | VAF 16/31 reads (52%) | called by muse, mutect2, varscan2
- PCDHGA12 | c.*724C>T | 3'UTR (SNP) | VAF 44/174 reads (25%) | called by muse, mutect2, varscan2
- PDGFC | c.*1991A>G | 3'UTR (SNP) | VAF 16/43 reads (37%) | called by muse, mutect2, varscan2
- PGR | c.*1148T>G | 3'UTR (SNP) | VAF 25/51 reads (49%) | called by muse, mutect2, varscan2
- PLAAT3 | c.*1413C>T | 3'UTR (SNP) | VAF 36/79 reads (46%) | catalogued as rs1181664425; called by muse, mutect2, varscan2
- POF1B | c.*890G>A | 3'UTR (SNP) | VAF 25/55 reads (45%) | catalogued as COSV99427049; called by muse, mutect2, varscan2
- PPCS | c.*217T>C | 3'UTR (SNP) | VAF 38/52 reads (73%) | called by muse, mutect2, varscan2
- PRKG1 | c.*3346C>A | 3'UTR (SNP) | VAF 23/44 reads (52%) | called by muse, mutect2, varscan2
- PRR14L | c.*1078A>T | 3'UTR (SNP) | VAF 36/70 reads (51%) | called by muse, mutect2, varscan2
- RALGPS2 | c.*1122dup | 3'UTR (INS) | VAF 25/77 reads (32%) | called by mutect2, pindel, varscan2
- RCC1 | c.-261-613A>G | Intron (SNP) | VAF 26/39 reads (67%) | called by muse, mutect2, varscan2
- RNF216 | c.*633G>A | 3'UTR (SNP) | VAF 89/129 reads (69%) | catalogued as rs753443942; called by muse, mutect2, varscan2
- ROBO1 | c.*568A>G | 3'UTR (SNP) | VAF 37/83 reads (45%) | called by muse, mutect2, varscan2
- RPL36A | chrX:101390856 T>C | 5'Flank (SNP) | VAF 50/102 reads (49%) | called by muse, mutect2, varscan2
- RPL36A | c.109+19A>C | Intron (SNP) | VAF 45/86 reads (52%) | called by muse, mutect2, varscan2
- SCLT1 | c.290+2437T>G | Intron (SNP) | VAF 27/53 reads (51%) | called by muse, mutect2, varscan2
- SDHAP2 | n.2000G>A | RNA (SNP) | VAF 98/226 reads (43%) | catalogued as rs1324802073; called by muse, varscan2
- SGCD | c.*6950C>G | 3'UTR (SNP) | VAF 32/199 reads (16%) | called by muse, mutect2, varscan2
- SLC25A23 | chr19:6436375 G>C | 3'Flank (SNP) | VAF 38/112 reads (34%) | called by muse, varscan2
- SLC5A9 | c.339+113G>A | Intron (SNP) | VAF 18/47 reads (38%) | catalogued as rs755924150; called by muse, mutect2, varscan2
- SLC6A4 | c.*2218A>G | 3'UTR (SNP) | VAF 20/46 reads (43%) | called by muse, mutect2, varscan2
- SPACA6 | chr19:51692630 C>T | 5'Flank (SNP) | VAF 53/106 reads (50%) | catalogued as rs771967356; called by muse, mutect2, varscan2
- TFE3 | c.*989G>T | 3'UTR (SNP) | VAF 39/74 reads (53%) | called by muse, mutect2, varscan2
- TMEM179 | c.*152C>T | 3'UTR (SNP) | VAF 33/66 reads (50%) | catalogued as rs570067943; called by muse, mutect2, varscan2
- TMEM234 | c.236-114A>T | Intron (SNP) | VAF 116/239 reads (49%) | called by muse, mutect2, varscan2
- TMSB4X | c.-17+228T>G | Intron (SNP) | VAF 46/92 reads (50%) | called by muse, mutect2, varscan2
- TRIM66 | c.*2148C>A | 3'UTR (SNP) | VAF 40/94 reads (43%) | called by muse, mutect2, varscan2
- TTC29 | chr4:146707019 A>C | 3'Flank (SNP) | VAF 24/46 reads (52%) | called by muse, mutect2, varscan2
- TTC39A | c.1161+1264G>A | Intron (SNP) | VAF 5/94 reads (5%) | called by muse, mutect2
- UBE2D3 | c.-262A>T | 5'UTR (SNP) | VAF 48/107 reads (45%) | called by muse, mutect2, varscan2
- VMA21 | c.*227A>T | 3'UTR (SNP) | VAF 22/52 reads (42%) | called by muse, mutect2, varscan2
- WDR62 | c.2972-11C>T | Intron (SNP) | VAF 16/50 reads (32%) | called by muse, mutect2, varscan2
- XIAP | c.*5929G>A | 3'UTR (SNP) | VAF 35/64 reads (55%) | catalogued as rs770052798; called by muse, mutect2, varscan2
- ZBTB42 | c.*1135G>A | 3'UTR (SNP) | VAF 50/109 reads (46%) | catalogued as rs983187536; called by muse, mutect2, varscan2
- ZNF41 | chrX:47483788 G>A | 5'Flank (SNP) | VAF 68/158 reads (43%) | called by muse, mutect2, varscan2
- ZNF449 | c.355-731A>C | Intron (SNP) | VAF 34/71 reads (48%) | called by muse, mutect2, varscan2
- ZNF488 | c.*1919G>A | 3'UTR (SNP) | VAF 88/165 reads (53%) | catalogued as rs782061773; called by muse, mutect2, varscan2
- ZNF614 | chr19:52013224 C>T | 3'Flank (SNP) | VAF 20/33 reads (61%) | called by muse, mutect2, varscan2
